Somatic mutation profile of tumor specimen MP2PRT-PATWVD-TMP1-A (aliquot MP2PRT-PATWVD-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATWVD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,356 days).
Specimen MP2PRT-PATWVD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 901a2451-df06-42e7-9592-de2b72f2e417.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATWVD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATWVD-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e1f5a85-fe12-48c2-a5ad-faa1979ec83b

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Frame Shift Ins 4, Silent 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP9A | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 59/303 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.018); catalogued as rs377421166, COSV58767168; called by muse, mutect2, varscan2
- RASSF2 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 53/270 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs778467935, COSV101040914; called by muse, varscan2
- TPH2 | c.952C>A p.H318N | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100421802; called by muse, mutect2, varscan2
- ANKFY1 | c.616_617dup p.S206Rfs*9 | Frame Shift Ins (INS) | VAF 40/287 reads (14%) | called by mutect2, pindel, varscan2
- ATP2A2 | c.989dup p.N330Kfs*46 | Frame Shift Ins (INS) | VAF 38/333 reads (11%) | called by mutect2, pindel, varscan2
- CEBPB | c.635dup p.Y213Lfs*28 | Frame Shift Ins (INS) | VAF 92/747 reads (12%) | called by mutect2, pindel, varscan2
- KMT2D | c.7199dup p.R2401Sfs*33 | Frame Shift Ins (INS) | VAF 58/624 reads (9%) | called by mutect2, pindel
- MEIKIN | c.686C>A p.A229D | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.381); called by mutect2, varscan2
- XIRP2 | c.8277G>T p.Q2759H (on ENST00000628543; = p.Q2934H on NM_152381.6) | Missense Mutation (SNP) | VAF 75/296 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- ZADH2 | c.839G>A p.G280D | Missense Mutation (SNP) | VAF 14/360 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- IFRD2 | c.333C>T p.C111= | Silent (SNP) | VAF 83/371 reads (22%) | called by muse, mutect2, varscan2
- PCK1 | c.495C>T p.Y165= | Silent (SNP) | VAF 63/456 reads (14%) | catalogued as rs751497442; called by muse, mutect2, varscan2
- IGHV3-23 | chr14:106268605 ins CCCCGGGCGGGC | 3'Flank (INS) | VAF 20/176 reads (11%) | called by mutect2, pindel
